Somatic mutation profile of tumor specimen BA2987D (aliquot aq-BA2987D) from BEATAML1.0 case 2224, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 52.2 years (19,082 days).
Specimen BA2987D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6121caf7-8b6a-41ff-8462-60e1aa0002db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2478D (Solid Tissue Normal), aliquot aq-BA2478D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8855335-c952-4259-a523-4689a1c51d26

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 10/32 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by muse, mutect2
- MYC | c.176C>A p.P59Q (on ENST00000377970; = p.P74Q on NM_002467.6) | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52368162, COSV52368882, COSV52375206; called by muse, mutect2
- BAG6 | c.2528G>T p.S843I (on ENST00000676571; = p.S796I on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.156); called by muse, mutect2
- DNAH1 | c.1053C>A p.V351= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- HSH2D | c.216-14C>A | Intron (SNP) | VAF 3/42 reads (7%) | catalogued as rs1269444221; called by muse, mutect2
